TCGA case TCGA-V4-A9ES — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c510a423-6ab1-431e-9248-d2ac91fdedba

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 54 years; Year of birth: 1956; Vital status: Dead; Days to death: 3,255 days (8.9 years); Year of death: 2020.

Diagnoses (2)
1. Mixed epithelioid and spindle cell melanoma (the primary disease): ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 54.9 years (20,054 days); Year of diagnosis: 2011; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T3b; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,255 days (8.9 years); Sites of involvement: Eye, Choroid / Eye, Ciliary Body.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 16.
   Pathology details: Consistent pathology review: No; Epithelioid cell percent range: 31-60%; Extrascleral extension present: No; Measurement type: Echographic; Spindle cell percent range: 31-60%; Tumor depth measurement: 12.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -4 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,355 days (3.7 years); Residual disease: R0; Treatment anatomic sites: Liver.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fotemustine; Days to treatment start: 1,451 days (4.0 years); Number of cycles: 7; Treatment dose: 175 mg; Treatment outcome: Treatment Stopped Due to Toxicity; Reason treatment ended: Adverse Event.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Pembrolizumab; Treatment intent type: Salvage; Days to treatment start: 2,396 days (6.6 years); Number of cycles: 7; Treatment dose: 150 mg; Treatment outcome: No Response; Reason treatment ended: Other.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Mixed epithelioid and spindle cell melanoma), site: Liver. Age at diagnosis: 58.5 years (21,353 days); Days to diagnosis: 1,299 days (3.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (6 entries)
- Days to follow up: 1,027 days (2.8 years); Disease response: Tumor Free.
- Days to follow up: 1,150 days (3.1 years); Disease response: Tumor Free.
- Day 1,299 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,299 days (3.6 years).
- Days to follow up: 1,328 days (3.6 years); Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,328 days (3.6 years).
- Days to follow up: 1,511 days (4.1 years); Disease response: With Tumor.
- Days to follow up: 3,255 days (8.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 32.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 156 cm; BMI: 27.9.
- Eye color: Brown.
- Comorbidities: Nevus of Ota.

Exposures
- Tobacco smoking status: Current Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9ES-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 40 mg.
  Slide TCGA-V4-A9ES-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9ES-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9ES-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology, Tumor tissue site list: Submitted tumor site: Ciliary body.
- Primary pathology, Tumor morphology list, Tumor morphology 1: Histologic diagnosis: Epithelioid Cell.
- Primary pathology, Tumor morphology list, Tumor morphology 2: Histologic diagnosis: Spindle Cell.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 1 loss; Cytogenetic abnormality type: Chromosome 3 loss.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,511 days; disease-specific survival: no event (censored), 1,511 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,299 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9ES-01A-11D-A39V-01): tumor purity 1, ploidy 1.85, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Loss 3
- comorbidity: ota nevus
- days to imaging: 2572
- days to metastasis: 1328
- days to outcome: 2980
- days to pharm therapy imaging 1: 1789
- days to pharm therapy imaging 2: 2676
- days to procedure 1: -4
- days to procedure 2: 1355
- diagnosis: melanoma
- disease status at death: Evidence of Disease
- drug name 1: fotemustin
- imaging type: liver MRI
- line of therapy 1: first
- line of therapy 2: second
- m stage: M0
- morphologic subtype: epithelioid
- n stage: N0
- number cycles 1: 7
- number cycles 2: 7
- performance status scale: Karnofsky
- performance status score: 1
- pharm therapy dose units 1: mg
- pharm therapy dose units 2: mg
- pharm therapy evaluated by imaging 1: yes
- pharm therapy evaluated by imaging 2: Yes
- pharm therapy imaging type 1: MRI
- pharm therapy imaging type 2: MRI
- pharm therapy status 1: treatment discontinued
- pharm therapy status 2: treatment discontinued
- pharm therapy status reason 1: Toxicity
- pharm therapy status reason 2: Lack of Response
- procedure type 2: right hepatectomy
- resection status 1: R0
- resection status 2: R0
- smoking status: smoker
- staging system: AJCC
- t stage: T3b
- test methodology: aCGH
- test result: intermediate risk
- unresectable 1: no
- unresectable 2: no
